Gene-level copy-number profile of tumor specimen C3N-00574-01 from CPTAC case C3N-00574, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 40.7 years (14,867 days).
Specimen C3N-00574-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43741299-17e9-480b-bf10-4af76e9cf453.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00574-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,746 have no estimate.
https://portal.gdc.cancer.gov/files/069ebbe8-924b-46d4-9704-85a272689573

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 14,571; copy number 2: 38,427; copy number 3: 4,125; copy number 4: 1,623; copy number 5: 1; copy number 7: 23; copy number 8: 8; copy number 9: 21; copy number 10: 8; copy number 11: 3; copy number 14: 4; copy number 16: 2; copy number 17: 17; copy number 20: 3; copy number 21: 6; copy number 26: 1; copy number 27: 3; copy number 30: 3; copy number 35: 12; copy number 41: 10; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 128 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,546,426–41,933,046, 19 genes, copy number 11–17 (within-gene range 3–17): FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL.
- chr7:50,839,363–51,729,716, 12 genes, copy number 7 (within-gene range 2–7): AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1.
- chr7:53,187,388–55,798,876, 49 genes, copy number 7–41 (within-gene range 4–41): HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, AC092647.4, CICP12.
- chr7:65,814,672–65,814,775, 1 gene, copy number 9: RNU6-912P.
- chr8:127,686,343–127,742,951, 2 genes, copy number 20: CASC11, MYC.
- chr8:128,220,504–128,220,803, 1 gene, copy number 10: RN7SKP226.
- chr8:130,052,104–130,443,674, 1 gene, copy number 9 (within-gene range 3–10): ASAP1.
- chr8:130,162,972–130,362,461, 3 genes, copy number 9 (within-gene range 9–10): AC103725.1, AC009682.1, AC139019.1.
- chr8:131,712,512–131,712,980, 1 gene, copy number 10: AC060788.1.
- chr8:132,120,859–132,675,592, 3 genes, copy number 7–10: KCNQ3, HPYR1, LRRC6.
- chr8:133,392,211–133,571,940, 5 genes, copy number 9–20: AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:141,055,290–141,060,596, 1 gene, copy number 14: AC100860.1.
- chr12:57,747,727–57,756,013, 1 gene, copy number 21 (within-gene range 2–21): CDK4.
- chr12:57,755,103–57,968,399, 18 genes, copy number 8–27: MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1.
- chr12:58,087,892–58,105,935, 3 genes, copy number 14: LINC02403, AC090643.1, AC090643.2.
- chr12:58,544,124–59,064,238, 6 genes, copy number 30–50: AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:59,450,673–59,450,772, 1 gene, copy number 26: RNU6-871P.
- chr14:18,395,626–18,412,264, 1 gene, copy number 5: CR383658.2.

Autosomal genes at a single copy (total copy number 1): 13,017. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
